Somatic mutation profile of cancer-model specimen HCM-BROD-0455-C71-85A (3D Neurosphere, passage 4; aliquot HCM-BROD-0455-C71-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-BROD-0455-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-BROD-0455-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf03e29c-9e2c-4a82-9bc8-122550cbdf9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0455-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0455-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dd5274b-c4a9-47fd-9e15-cb239ea25ddc

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 11, Intron 3, Frame Shift Del 3, RNA 3, Nonsense Mutation 2, In Frame Ins 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2316_2321dup p.H773_V774dup | In Frame Ins (INS) | VAF 136/668 reads (20%) | hotspot (GDC flag); catalogued as COSV51800933, COSV51820458; called by mutect2, pindel, varscan2
- MYH6 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 83/786 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691839; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 539/541 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEP162 | c.2396_2399del p.D799Vfs*9 | Frame Shift Del (DEL) | VAF 78/84 reads (93%) | catalogued as rs751294869; called by mutect2, pindel, varscan2
- CFHR5 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 171/318 reads (54%) | catalogued as rs771772296, COSV56817974; called by muse, mutect2, varscan2
- CLCN6 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 140/258 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770022946, COSV56738750; called by muse, mutect2, varscan2
- COL1A2 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 344/811 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs764373659, COSV99800278; called by muse, mutect2, varscan2
- ELMO1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.027); catalogued as COSV60299879, COSV60302276; called by muse, mutect2, varscan2
- FLG | c.7769A>G p.N2590S | Missense Mutation (SNP) | VAF 557/1137 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1034363980, COSV64241402; called by muse, mutect2, varscan2
- FLG | c.5529C>G p.H1843Q | Missense Mutation (SNP) | VAF 361/916 reads (39%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.917); catalogued as COSV100911597; called by muse, mutect2, varscan2
- FN1 | c.2856G>C p.Q952H | Missense Mutation (SNP) | VAF 527/757 reads (70%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1196629506, COSV104396174; called by muse, mutect2, varscan2
- GPR173 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); catalogued as rs782340108, COSV60234702; called by muse, mutect2, varscan2
- HMCN2 | c.11725G>A p.G3909R | Missense Mutation (SNP) | VAF 316/433 reads (73%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs561629937; called by muse, mutect2, varscan2
- KRT8 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 721/1284 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs764622352, COSV53176304, COSV99509888; called by muse, mutect2, varscan2
- PAN3 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as COSV56703082; called by muse, mutect2, varscan2
- PCDHGA1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 78/514 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs866208625, COSV65295357; called by muse, mutect2, varscan2
- PDILT | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 153/274 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs750176775, COSV56704382; called by muse, mutect2, varscan2
- PLCB1 | c.2208+1G>A p.X736_splice | Splice Site (SNP) | VAF 124/286 reads (43%) | catalogued as rs1235234848; called by muse, mutect2, varscan2
- PTPRQ | c.5836G>A p.V1946I (on ENST00000616559; = p.V1904I on NM_001145026.2) | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.341); catalogued as rs575071305, COSV57056778; called by muse, mutect2, varscan2
- PTPRZ1 | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 104/452 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs759034684; called by muse, mutect2, varscan2
- RNASEL | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 350/628 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758397188; called by muse, mutect2, varscan2
- SLC5A11 | c.1777G>A p.V593I | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs572775623, COSV61740330; called by mutect2, varscan2
- SST | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 141/370 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs764051709, COSV99809777; called by muse, mutect2, varscan2
- ZNF354A | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 170/217 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs148789422; called by muse, mutect2, varscan2
- AOC3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 612/855 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- BFSP1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 199/420 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C14orf39 | c.1161A>T p.E387D | Missense Mutation (SNP) | VAF 82/82 reads (100%) | SIFT tolerated (0.61); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- EPB41L4B | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 78/97 reads (80%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.043); called by muse, mutect2
- FAM47A | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 219/223 reads (98%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GNPDA2 | c.300T>A p.D100E | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRIN3A | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 41/767 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, mutect2
- HOXA7 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 591/1472 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IKZF1 | c.1480A>C p.M494L | Missense Mutation (SNP) | VAF 376/1346 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- IL34 | c.543A>T p.K181N | Missense Mutation (SNP) | VAF 61/94 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIAA0408 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KLF15 | c.410T>C p.F137S | Missense Mutation (SNP) | VAF 286/503 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL1 | c.37C>A p.H13N | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); called by muse, mutect2
- KMT2E | c.638T>G p.I213S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- LAMC1 | c.1687G>C p.A563P | Missense Mutation (SNP) | VAF 96/162 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- LRRC9 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- MCPH1 | c.55A>G p.N19D | Missense Mutation (SNP) | VAF 156/312 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MED16 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 40/613 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.098); called by muse, mutect2
- PLVAP | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 225/599 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM13 | c.209T>C p.L70S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SELE | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOGA3 | c.2019C>G p.I673M | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SRC | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STAG2 | c.3311del p.L1104* | Frame Shift Del (DEL) | VAF 72/97 reads (74%) | called by mutect2, pindel, varscan2
- TONSL | c.3928T>G p.F1310V | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZBED9 | c.938del p.N313Ifs*30 | Frame Shift Del (DEL) | VAF 127/206 reads (62%) | called by mutect2, pindel, varscan2
- ACVRL1 | c.1390C>T p.L464= | Silent (SNP) | VAF 302/844 reads (36%) | catalogued as CD126266; called by muse, mutect2, varscan2
- ASXL1 | c.2616C>T p.C872= | Silent (SNP) | VAF 82/1220 reads (7%) | catalogued as rs779837740, COSV100037457; called by muse, mutect2
- FBLL1 | c.501C>T p.I167= | Silent (SNP) | VAF 13/443 reads (3%) | called by muse, mutect2
- MAP3K4 | c.3801A>T p.S1267= | Silent (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- OR1S1 | c.810C>T p.G270= | Silent (SNP) | VAF 216/436 reads (50%) | catalogued as rs769712075, COSV58708680; called by muse, mutect2, varscan2
- PKM | c.165C>G p.S55= | Silent (SNP) | VAF 222/473 reads (47%) | called by muse, mutect2, varscan2
- PRF1 | c.1470C>T p.D490= | Silent (SNP) | VAF 409/409 reads (100%) | catalogued as rs759727585, COSV64615339; called by muse, mutect2, varscan2
- PROKR2 | c.990C>T p.T330= | Silent (SNP) | VAF 728/1396 reads (52%) | catalogued as rs551444582, CD100862, COSV54087703; called by muse, mutect2, varscan2
- RAPGEF6 | c.3219C>T p.S1073= | Silent (SNP) | VAF 61/314 reads (19%) | called by muse, mutect2, varscan2
- RNF17 | c.4836G>A p.P1612= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as rs576396754, COSV99692481; called by muse, mutect2, varscan2
- SARAF | c.69G>C p.L23= | Silent (SNP) | VAF 40/377 reads (11%) | catalogued as rs113461374; called by muse, mutect2, varscan2
- AFF4 | c.964-42C>T | Intron (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- AL450442.1 | n.680A>C | RNA (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- BOD1P2 | n.146C>T | RNA (SNP) | VAF 79/104 reads (76%) | catalogued as rs910280143; called by muse, mutect2, varscan2
- MRPL18 | c.52+19del | Intron (DEL) | VAF 172/254 reads (68%) | called by mutect2, pindel, varscan2
- PCYT1A | c.117+3111A>T | Intron (SNP) | VAF 147/266 reads (55%) | called by muse, mutect2, varscan2
- TLE3 | c.-201C>G | 5'UTR (SNP) | VAF 119/246 reads (48%) | called by muse, mutect2, varscan2
- UBTFL2 | n.405A>G | RNA (SNP) | VAF 364/1199 reads (30%) | called by muse, mutect2, varscan2
